Somatic mutation profile of tumor specimen MP2PRT-PAVYRC-TMP1-A (aliquot MP2PRT-PAVYRC-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVYRC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (721 days).
Specimen MP2PRT-PAVYRC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9322d78b-fad1-450a-b5aa-2bf43cc2cb5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVYRC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVYRC-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aee0f378-1e6a-4f22-af50-8f0d13fadd97

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 82/280 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- DMD | c.5307C>G p.H1769Q | Missense Mutation (SNP) | VAF 132/296 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772581752, CD068544, COSV100820852; called by muse, mutect2, varscan2
- HOXD1 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 79/857 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1433714139, COSV100514088; called by muse, mutect2
- LRIG3 | c.2143G>A p.V715I | Missense Mutation (SNP) | VAF 200/462 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs374158553; called by muse, mutect2, varscan2
- MINK1 | c.3377G>A p.R1126Q | Missense Mutation (SNP) | VAF 42/608 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs752334893; called by muse, mutect2
- NPPC | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 82/728 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs773742831; called by muse, mutect2, varscan2
- SCNN1A | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 318/688 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs757014172, COSV57435164; called by muse, mutect2, varscan2
- SLC25A31 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 68/756 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs368916292; called by muse, mutect2
- SPTBN5 | c.1087C>T p.R363* | Nonsense Mutation (SNP) | VAF 274/605 reads (45%) | catalogued as rs766735807; called by muse, mutect2, varscan2
- MATN4 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 66/683 reads (10%) | PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PARS2 | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 15/428 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); called by muse, mutect2
- TSHZ3 | c.1997G>C p.S666T | Missense Mutation (SNP) | VAF 34/848 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.014); called by muse, mutect2
- CA9 | c.1134G>A p.T378= | Silent (SNP) | VAF 37/573 reads (6%) | catalogued as rs761778575, COSV61405892; called by muse, mutect2
- PSD2 | c.510C>T p.S170= | Silent (SNP) | VAF 295/602 reads (49%) | catalogued as rs199679832, COSV51201363; called by muse, mutect2, varscan2
- S1PR1 | c.1131C>T p.N377= | Silent (SNP) | VAF 140/311 reads (45%) | catalogued as COSV59513181; called by muse, mutect2, varscan2
